Gene-level copy-number profile of tumor specimen TCGA-CQ-7068-01A from TCGA case TCGA-CQ-7068, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 80.8 years (29,530 days).
Specimen TCGA-CQ-7068-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.a3a3e8ac-0a4d-471e-abaf-869184483285.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CQ-7068-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d5725179-834a-4c39-9aa7-9024ae5add94

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 2,729; copy number 2: 51,206; copy number 3: 4,023; copy number 4: 1,079; copy number 5: 758.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CQ-7068-01A-11D-2077-01): tumor purity 0.63, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,524,307–22,128,103, 18 genes: SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 758 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–21,559,900, 304 genes, copy number 5 (within-gene range 0–5) (broad region; genes not listed).
- chr9:22,203,990–43,045,120, 454 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 308. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
